Somatic mutation profile of tumor specimen TCGA-IS-A3K7-01A (aliquot TCGA-IS-A3K7-01A-11D-A21Q-09) from TCGA case TCGA-IS-A3K7, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 63.0 years (23,022 days).
Specimen TCGA-IS-A3K7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf7285e6-d593-484b-a62a-8cc2e9b16d2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IS-A3K7-10A (Blood Derived Normal), aliquot TCGA-IS-A3K7-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c16f434f-93cb-4941-ad35-bc52a93cf758

The open-access MAF lists 107 somatic variants for this specimen: 84 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, Nonsense Mutation 10, Splice Region 3, RNA 2, Splice Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPRED1 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs121434314, CM074581; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV101658570; called by muse, mutect2
- AKAP12 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99482924; called by muse, mutect2
- AKAP3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as rs369931580, COSV99961755; called by muse, mutect2
- ALK | c.1710G>C p.E570D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as COSV66573850; called by muse, mutect2, varscan2
- ANKMY1 | c.2619-1G>A p.X873_splice | Splice Site (SNP) | VAF 26/107 reads (24%) | catalogued as rs1003333351, COSV99801002; called by muse, varscan2
- BRCA2 | c.5410G>A p.V1804I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as CD042858, COSV99061743; called by muse, mutect2, varscan2
- CBLB | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.054); catalogued as rs542952599; called by muse, mutect2, varscan2
- DDX56 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1232956673; called by muse, mutect2, varscan2
- DGCR2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.591); catalogued as rs780808326; called by muse, mutect2, varscan2
- DPEP1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs879195013, COSV55359611, COSV99878702; called by muse, mutect2, varscan2
- EEF1G | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs752473849; called by muse, mutect2, varscan2
- FAM220A | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs576104923, COSV57626540; called by muse, mutect2, varscan2
- FREM2 | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99746197; called by muse, mutect2, varscan2
- GLTPD2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs1383084633; called by muse, mutect2, varscan2
- HTR3E | c.212C>T p.A71V (on ENST00000415389 / NM_001256613.1; = p.A86V on NM_182589.2) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs762903193, COSV58948681; called by muse, mutect2, varscan2
- KMT2D | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.636); catalogued as COSV56464019; called by muse, mutect2, varscan2
- LIFR | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54700414; called by muse, mutect2, varscan2
- MBD3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.926); catalogued as rs1156358847, COSV50084027; called by muse, mutect2, varscan2
- MED14 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.569); catalogued as COSV61356467; called by muse, mutect2, varscan2
- MKI67 | c.1772C>G p.A591G | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs768067622; called by muse, mutect2, varscan2
- MMRN2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100922460; called by muse, mutect2, varscan2
- MVD | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1465103764, COSV99964706; called by muse, mutect2
- PCDH10 | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.325); catalogued as rs779122845, COSV52102642, COSV99994817; called by muse, mutect2, varscan2
- PHYHIP | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV100394948, COSV58688669; called by muse, mutect2, varscan2
- PKD2 | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CD076888, COSV99416692; called by muse, mutect2
- PM20D1 | c.829T>C p.L277= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs780500656; called by muse, mutect2, varscan2
- RSAD1 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99364073; called by muse, mutect2
- SNAI3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1209111594; called by muse, mutect2, varscan2
- SPACA1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs746695214, COSV52758995; called by muse, mutect2, varscan2
- SUSD3 | c.748G>C p.A250P | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.557); catalogued as rs145889796; called by muse, mutect2, varscan2
- UGT3A2 | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99236353; called by muse, mutect2, varscan2
- WDR3 | c.792A>C p.R264= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100832144; called by muse, mutect2, varscan2
- ZNF831 | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs747755634; called by muse, mutect2, varscan2
- ABCA8 | c.3907A>G p.T1303A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ATL2 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- CACNA1E | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2
- DAGLA | c.1485T>G p.F495L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DLX6 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRP2 | c.2731C>G p.P911A | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- E2F3 | c.529dup p.T177Nfs*4 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- EIF3F | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- ENTPD8 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERAS | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- GAPDH | c.989A>C p.H330P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GCOM1 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- GLP1R | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- HERC2P3 | n.1380T>A | Splice Region (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- JADE1 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by mutect2, varscan2
- KIF2B | c.1605A>T p.R535S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LCA5 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- LRFN1 | c.1474T>G p.C492G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC30 | c.906A>T p.*302Cext*? | Nonstop Mutation (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- LY9 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2
- MAGED1 | c.1441T>C p.Y481H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K20 | c.1973G>A p.G658D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPL44 | c.931A>G p.R311G | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC16 | c.6460T>A p.S2154T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- NUAK1 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR4C15 | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARP14 | c.4333T>C p.W1445R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCDHGA10 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PDGFRB | c.2548G>T p.D850Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PHLDB1 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRRC2C | c.5093A>G p.E1698G (on ENST00000367742; = p.E1696G on NM_015172.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRSS16 | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHBG | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SDK2 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.292); called by muse, mutect2
- SERTAD2 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC6A7 | c.1071C>G p.D357E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPACA1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2
- SULF1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCF19 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by mutect2, varscan2
- TLR10 | c.2004T>A p.Y668* | Nonsense Mutation (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- TSSK6 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- TUBB4B | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); called by muse, mutect2
- UNC13C | c.4702C>G p.L1568V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- UTP3 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- ZNF226 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF347 | c.641T>G p.F214C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF425 | c.1220T>A p.V407D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZSCAN20 | c.1051C>G p.H351D | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AUTS2 | c.2118A>C p.A706= | Silent (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- CLDN4 | c.48G>C p.L16= | Silent (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- DCC | c.2880T>G p.P960= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- DISP3 | c.2145G>A p.E715= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- ESX1 | c.885A>G p.P295= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- FOXK2 | c.966C>T p.S322= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV58881512, COSV58881799; called by muse, mutect2, varscan2
- IL5RA | c.678C>A p.P226= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99842565; called by muse, mutect2
- IRF9 | c.486C>A p.S162= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1479393723; called by muse, mutect2, varscan2
- LZTS3 | c.1203G>A p.K401= (on ENST00000329152; = p.K355= on NM_001282533.2) | Silent (SNP) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- NHLRC2 | c.1344C>T p.H448= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs539942915; called by muse, mutect2, varscan2
- NOS3 | c.1095G>A p.R365= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs747233246; called by muse, mutect2, varscan2
- NTRK2 | c.1815C>A p.G605= (on ENST00000323115 / NM_001369534.1; = p.G621= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV52854262; called by muse, mutect2, varscan2
- OPA1 | c.2148T>A p.T716= (on ENST00000361510 / NM_130837.3; = p.T661= on NM_015560.3) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as CX126980, COSV62480550; called by muse, mutect2, varscan2
- OR51F2 | c.282C>T p.I94= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- RBMXL2 | c.261G>A p.P87= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs780712714, COSV60981228; called by muse, mutect2
- SNCB | c.315A>G p.E105= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1307852802, COSV100031100; called by muse, mutect2, varscan2
- SPINK8 | c.27C>A p.I9= | Silent (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- SPNS3 | c.1410C>T p.Y470= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- SPRED1 | c.642G>T p.R214= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- STARD8 | c.2794C>T p.L932= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- TENM4 | c.5754C>T p.F1918= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1406976860, COSV53614946; called by muse, mutect2, varscan2
- SLC22A20P | n.1137C>G | RNA (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- TBC1D29P | n.2598G>A | RNA (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
